Surgical pathology report (de-identified scan), TCGA case TCGA-E7-A6MF, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Asterand, specimen TCGA-E7-A6MF-01A (Primary Tumor).

Patient ID:

Surgical Date:

Gross Description: In bladder, there is an invasive and protruded masse, ill - margins with 2.2x1..5x1cm in size, soft and gray surface.

Microscopic Description: Tumor is density. Tumor cells are hyperplastic to arrange to form papillary or nest or groups or cords. Tumor cells have moderate and basophilic or vacuolated cytoplasm. Nuclei are enlarged and varriability in shape and size, irregular nuclear membranes, nucleoli and abnormal chromatin patterns. Mitoses are present. Tumor invades in inner muscle propria

Diagnosis Details: Infiltrating urothelial carcinoma, low-grade, infiltrating in inner muscularis propria

Comments:

Formatted Path Reports: BLADDER TISSUE CHECKLIST

Specimen type: Cystectomy

Tumor site: Bladder

Tumor size: 2.2 x 1.5 x 1 cm

Tumor features: None specified

Histologic type: Transitional cell carcinoma, papillary

Histologic grade: Moderately differentiated

Tumor extent: Superficial muscle (innner half)

Lymph nodes: Not specified

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

ICD-O-3
Carcinoma, transitional cell
papillary 8130/3
Site C67.9
path Bladder NOS C67.9
QAD 7/3/13

Dual/Synchronous Primary		Noted

Source: NCI Genomic Data Commons file cdfc8f2f-dfe1-469c-a6c8-ca83e198e7a9 (TCGA-E7-A6MF.3431AE0E-2696-4DE7-BBA8-E3CD0185632B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).